Somatic mutation profile of tumor specimen da3d7876-ca79-4f21-a00e-27e6b6 (aliquot da3d7876-ca79-4f21-a00e-27e6b6_D6_1) from CPTAC case 11BR022, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 48.6 years (17,763 days).
Specimen da3d7876-ca79-4f21-a00e-27e6b6: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e80dc5e-1af7-4464-9b23-0111b4f94a8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 19a415b6-f700-44ae-b704-348eda (Blood Derived Normal), aliquot 19a415b6-f700-44ae-b704-348eda_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b04342d0-26eb-4654-946e-0f5d60a69682

The open-access MAF lists 23 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 7, Splice Site 3, Splice Region 1, 3'UTR 1, Nonsense Mutation 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.2426A>G p.Q809R | Missense Mutation (SNP) | VAF 75/445 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs931676601, COSV57250012; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 23/163 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99274756; called by muse, mutect2
- BICDL1 | c.1147C>T p.R383* | Nonsense Mutation (SNP) | VAF 16/349 reads (5%) | catalogued as COSV57494020; called by muse, mutect2
- CBFB | c.165+1del p.X55_splice | Splice Site (DEL) | VAF 10/36 reads (28%) | catalogued as COSV51996680, COSV51997241, COSV51997594, COSV52002060; called by mutect2, pindel, varscan2
- CCDC183 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 48/452 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs369725195, COSV100273643; called by muse, mutect2, varscan2
- COL18A1 | c.1612G>A p.V538M (on ENST00000359759 / NM_130444.3; = p.V303M on NM_030582.4) | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs376829205; called by muse, mutect2, varscan2
- F13A1 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs201444282, COSV53554345; called by muse, mutect2
- FLNC | c.4927+2T>G p.X1643_splice | Splice Site (SNP) | VAF 22/305 reads (7%) | catalogued as COSV57959496; called by muse, mutect2
- NCOR1 | c.2691-1G>T p.X897_splice | Splice Site (SNP) | VAF 14/76 reads (18%) | catalogued as COSV51975936; called by muse, mutect2, varscan2
- TSNAX | c.123A>T p.S41= | Splice Region (SNP) | VAF 14/130 reads (11%) | catalogued as COSV64146368; called by muse, mutect2
- UBTFL1 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 34/363 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs769544073, COSV73297912; called by muse, mutect2
- CKAP5 | c.4955A>G p.D1652G (on ENST00000529230 / NM_001008938.4; = p.D1592G on NM_014756.3) | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ATP10B | c.4236A>C p.S1412= | Silent (SNP) | VAF 58/358 reads (16%) | called by muse, mutect2, varscan2
- KIF19 | c.2328T>A p.T776= | Silent (SNP) | VAF 21/127 reads (17%) | called by muse, mutect2, varscan2
- KIRREL1 | c.1251C>T p.S417= | Silent (SNP) | VAF 25/203 reads (12%) | called by muse, mutect2, varscan2
- PRKCQ | c.1608G>A p.T536= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs751782966, COSV54107032; called by muse, mutect2, varscan2
- PTGIS | c.555G>T p.A185= | Silent (SNP) | VAF 56/355 reads (16%) | catalogued as rs572751437, COSV54838451, COSV99720773; called by muse, mutect2, varscan2
- SURF6 | c.576G>A p.P192= | Silent (SNP) | VAF 7/147 reads (5%) | catalogued as rs782312339; called by muse, mutect2
- TEX13C | c.1416C>T p.G472= | Silent (SNP) | VAF 26/331 reads (8%) | catalogued as rs754384831; called by muse, mutect2
- BUB3 | c.*1254C>G | 3'UTR (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- LILRB1 | c.1510+18C>T | Intron (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- TPRX2P | n.725G>A | RNA (SNP) | VAF 38/213 reads (18%) | catalogued as rs773650615; called by muse, mutect2, varscan2
